Somatic mutation profile of tumor specimen TARGET-10-PARUEU-09A (aliquot TARGET-10-PARUEU-09A-01D) from TARGET case TARGET-10-PARUEU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,036 days).
Specimen TARGET-10-PARUEU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ff85536-8a65-4f54-bb33-077a2b21345d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUEU-10A (Blood Derived Normal), aliquot TARGET-10-PARUEU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/283e37ee-1338-4988-a67b-d645fcb6380b

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 3'UTR 1, 5'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11B | c.1354G>A p.E452K (on ENST00000357195 / NM_001282237.2; = p.E381K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61739449; called by muse, mutect2, varscan2
- CCDC7 | c.3101C>T p.P1034L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.108); catalogued as COSV56552166; called by muse, mutect2, varscan2
- DNM2 | c.1610G>A p.G537D (on ENST00000355667 / NM_001005360.3; = p.G533D on NM_004945.3) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV58971972; called by muse, mutect2, varscan2
- LRP3 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs759465405, COSV53507564; called by muse, mutect2, varscan2
- NOTCH1 | c.4775T>C p.F1592S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024854, COSV53033159; called by muse, mutect2
- PHF6 | c.129_130insGGATAAGAA p.H43_K44insG* | Nonsense Mutation (INS) | VAF 63/82 reads (77%) | catalogued as COSV59699971, COSV59700160, COSV59706640; called by mutect2, pindel, varscan2
- SULT2A1 | c.682A>G p.M228V | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV55766529; called by muse, mutect2, varscan2
- ZNF618 | c.1387G>A p.E463K (on ENST00000374126 / NM_001318042.2; = p.E370K on NM_133374.2) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs754922865, COSV55928747; called by muse, mutect2, varscan2
- TREX2 | c.35G>T p.S12I | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FLG2 | c.5523C>T p.D1841= | Silent (SNP) | VAF 86/179 reads (48%) | catalogued as rs778100266, COSV66170417; called by muse, mutect2, varscan2
- IQCN | c.2865C>T p.V955= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- C1QTNF3 | c.352-21G>A | Intron (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- IL1RL2 | c.-33G>A | 5'UTR (SNP) | VAF 17/67 reads (25%) | catalogued as rs1157657790; called by muse, mutect2, varscan2
- TAL1 | c.*168T>G | 3'UTR (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
